Somatic mutation profile of tumor specimen TCGA-39-5029-01A (aliquot TCGA-39-5029-01A-01D-1441-08) from TCGA case TCGA-39-5029, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,713 days).
Specimen TCGA-39-5029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be3e3bbb-bb77-4c9a-934a-02a658e13ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5029-11A (Solid Tissue Normal), aliquot TCGA-39-5029-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/966fe171-a849-4dcc-a052-de54597d95fb

The open-access MAF lists 159 somatic variants for this specimen: 123 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 34, Nonsense Mutation 6, Splice Site 4, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.1501G>T p.G501* (on ENST00000502732 / NM_007314.4; = p.G486* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 46/206 reads (22%) | catalogued as COSV61010953; called by muse, mutect2, varscan2
- ACAP3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs12409951; called by muse, mutect2, varscan2
- ADAM9 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 78/908 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.589); catalogued as COSV65958692, COSV65961006; called by muse, mutect2
- ADAMTS16 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56977669; called by muse, mutect2, varscan2
- ADAMTS4 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.972); catalogued as COSV63487262; called by muse, mutect2, varscan2
- ADCYAP1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV52485715, COSV99327591; called by muse, varscan2
- AHNAK | c.14515A>G p.M4839V | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV57203383; called by muse, mutect2, varscan2
- AKAP13 | c.6099G>T p.Q2033H (on ENST00000394518 / NM_007200.5; = p.Q2037H on NM_006738.6) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63448031; called by muse, mutect2, varscan2
- ALDOA | c.917C>T p.A306V (on ENST00000642816 / NM_001243177.4; = p.A252V on NM_184041.5) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as rs888329113, COSV57631953; called by muse, mutect2, varscan2
- ANKRD30A | c.1573-1G>T p.X525_splice (on ENST00000611781; = p.X469_splice on NM_052997.2) | Splice Site (SNP) | VAF 38/159 reads (24%) | catalogued as COSV100653965, COSV64603630; called by muse, mutect2, varscan2
- ANKRD7 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV54553807; called by muse, mutect2, varscan2
- AR | c.2626C>A p.Q876K | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV65952959; called by muse, mutect2, varscan2
- ARHGAP39 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs745981568, COSV52766892; called by muse, mutect2, varscan2
- ATG3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV51925799; called by muse, mutect2, varscan2
- BCCIP | c.823T>A p.C275S | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV52938092; called by muse, mutect2, varscan2
- BLVRA | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV55512447; called by muse, mutect2, varscan2
- BUD23 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as rs1025573599, COSV56094175; called by muse, mutect2, varscan2
- C10orf53 | c.402T>A p.C134* | Nonsense Mutation (SNP) | VAF 20/192 reads (10%) | catalogued as COSV65108443; called by muse, mutect2, varscan2
- CACNA1A | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV64189421; called by muse, mutect2, varscan2
- CCM2L | c.1210G>C p.G404R (on ENST00000452892 / NM_001365692.1; = p.A382= on NM_080625.4) | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV52948993; called by muse, mutect2, varscan2
- CD1D | c.328+2T>C p.X110_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV63808359; called by muse, mutect2, varscan2
- CFAP53 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV53997993; called by muse, mutect2, varscan2
- CGNL1 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1474748647, COSV55563323; called by muse, mutect2, varscan2
- CMBL | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs780957157, COSV56982742, COSV56982761; called by muse, mutect2, varscan2
- CNTNAP5 | c.1350G>C p.W450C | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70471885; called by muse, mutect2, varscan2
- COL6A6 | c.2852C>A p.A951D | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62017389; called by muse, mutect2, varscan2
- CREB3L2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57792108; called by muse, mutect2, varscan2
- CSMD1 | c.3878C>A p.P1293H (on ENST00000520002; = p.P1292H on NM_033225.6) | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59280525; called by muse, mutect2, varscan2
- DENND5A | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs557614928, COSV60231261; called by muse, mutect2, varscan2
- DGKE | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV52348808; called by muse, mutect2
- DMD | c.9197C>T p.S3066L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs128626254, CM940363, COSV58891045; called by muse, mutect2, varscan2
- DNAH3 | c.7330G>A p.A2444T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146558827; called by muse, mutect2, varscan2
- DNAJC13 | c.5594A>G p.N1865S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as rs1017172253, COSV53445412; called by muse, mutect2, varscan2
- ESRRG | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63149550; called by muse, mutect2
- FGD4 | c.1219T>A p.Y407N | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56780205; called by muse, mutect2, varscan2
- FNDC3A | c.748A>G p.T250A (on ENST00000492622 / NM_001079673.2; = p.T194A on NM_014923.5) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV65694540; called by muse, mutect2, varscan2
- GCC2 | c.3592G>C p.E1198Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV59173882; called by muse, mutect2
- GFOD2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as COSV52056826; called by muse, mutect2, varscan2
- GOLGA2 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV70168032, COSV70168041; called by muse, mutect2, varscan2
- GPR45 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs766303852, COSV51522681, COSV99306712; called by muse, mutect2, varscan2
- GRIK3 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66135379; called by muse, mutect2, varscan2
- HELQ | c.1874A>G p.N625S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs376480242; called by muse, mutect2, varscan2
- HERC5 | c.781-2A>G p.X261_splice | Splice Site (SNP) | VAF 39/168 reads (23%) | catalogued as COSV52037162; called by muse, mutect2, varscan2
- HHIPL1 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58089086; called by muse, varscan2
- IFT172 | c.4076A>G p.D1359G | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53129578; called by muse, mutect2, varscan2
- IGKV1D-42 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs193096486; called by muse, mutect2, varscan2
- KIFC2 | c.1388G>C p.R463T | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs770584382, COSV56759809; called by muse, varscan2
- KIFC2 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958719907, COSV56759820; called by muse, varscan2
- KIT | c.2646G>A p.M882I | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55388214; called by muse, mutect2, varscan2
- KMT2C | c.6136C>A p.P2046T | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51285927; called by muse, mutect2, varscan2
- KRTAP13-1 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV62662801; called by muse, mutect2, varscan2
- LAMB1 | c.2489A>G p.N830S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758125105, COSV55961480; called by muse, mutect2, varscan2
- LGR4 | c.1253T>G p.L418R | Missense Mutation (SNP) | VAF 105/491 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64863384; called by muse, mutect2, varscan2
- LRP1B | c.7139C>T p.S2380L | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV67185242; called by muse, mutect2, varscan2
- LRP3 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV53502445; called by muse, mutect2, varscan2
- MACF1 | c.5585G>A p.G1862E | Missense Mutation (SNP) | VAF 103/205 reads (50%) | catalogued as COSV57105107; called by muse, mutect2, varscan2
- MAGEE2 | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as COSV64897219; called by muse, mutect2, varscan2
- MKI67 | c.4393G>C p.E1465Q | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1240353116, COSV64072464; called by muse, mutect2, varscan2
- MLIP | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV51425695; called by muse, mutect2, varscan2
- MORN1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66002543; called by muse, mutect2, varscan2
- MRPS35 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV50011132; called by muse, mutect2, varscan2
- MTBP | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1307418329, COSV59960774; called by muse, mutect2
- MTERF4 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV54087717; called by muse, mutect2, varscan2
- MUC17 | c.2867C>A p.T956N | Missense Mutation (SNP) | VAF 91/542 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV60279668; called by muse, mutect2, varscan2
- MYO18B | c.5228T>C p.L1743P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320295013, COSV59124929; called by muse, mutect2, varscan2
- NDUFAF5 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149637004, COSV65246561; called by muse, mutect2, varscan2
- NEB | c.4774A>C p.S1592R | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50808546, COSV51421565; called by muse, mutect2, varscan2
- NME3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51598885, COSV99167837; called by muse, mutect2, varscan2
- NOS2 | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as rs774237653, COSV58221609; called by muse, mutect2, varscan2
- NUDT16 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs1232963147, COSV100720810; called by muse, mutect2, varscan2
- NXPH3 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as COSV60871780; called by muse, mutect2, varscan2
- OIT3 | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61824937, COSV61825018; called by muse, mutect2, varscan2
- OR4B1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58881950; called by muse, mutect2, varscan2
- OR52A1 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV61091961; called by mutect2, varscan2
- OR8H2 | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 85/341 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV57943115; called by muse, mutect2, varscan2
- PARP4 | c.2639G>T p.C880F | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67960342; called by muse, mutect2, varscan2
- PCDH15 | c.5431C>G p.L1811V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV100222161, COSV57262039; called by muse, mutect2
- PCDHB7 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50753842; called by muse, mutect2, varscan2
- PCDHGA9 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as COSV53896701; called by muse, mutect2, varscan2
- PCNT | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as COSV64024921; called by muse, mutect2, varscan2
- PDCL2 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV55259142, COSV99823787; called by muse, mutect2, varscan2
- PHKA1 | c.79-2A>G p.X27_splice | Splice Site (SNP) | VAF 19/37 reads (51%) | catalogued as COSV59801551; called by muse, mutect2, varscan2
- PIK3C3 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56275841; called by muse, mutect2
- PIK3R2 | c.1488G>C p.Q496H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.478); catalogued as COSV55846669; called by muse, mutect2, varscan2
- PKHD1 | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV61860026; called by muse, mutect2, varscan2
- PLPPR1 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV66449625; called by muse, varscan2
- PLPPR1 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761281978, COSV66449631; called by muse, varscan2
- PRPF4 | c.898G>A p.A300T (on ENST00000374198 / NM_001322267.2; = p.A301T on NM_004697.5) | Missense Mutation (SNP) | VAF 257/742 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as COSV65252215; called by muse, mutect2, varscan2
- PRSS12 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs758744349, COSV56604055; called by muse, varscan2
- PSD | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV50041729; called by muse, mutect2, varscan2
- PTPN13 | c.3727A>C p.S1243R (on ENST00000411767 / NM_080683.3; = p.S1224R on NM_006264.3) | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV57402281; called by muse, mutect2, varscan2
- RB1CC1 | c.994A>T p.M332L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV50243053; called by muse, mutect2, varscan2
- SDR9C7 | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53288325; called by muse, mutect2, varscan2
- SERPINA6 | c.1182C>A p.S394R | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270243704, COSV58583330; called by muse, mutect2, varscan2
- SLC1A4 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52233531; called by muse, mutect2, varscan2
- SLC27A6 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV52479245, COSV99322511; called by muse, mutect2, varscan2
- SLC30A3 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs779313952, COSV51983954; called by muse, mutect2, varscan2
- SLC39A12 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV66194839; called by muse, mutect2, varscan2
- SMG1 | c.8210T>C p.V2737A | Missense Mutation (SNP) | VAF 75/424 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV67169459; called by muse, mutect2, varscan2
- SMG1 | c.3874C>T p.Q1292* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV67169462; called by muse, mutect2, varscan2
- SPAM1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56141123; called by muse, mutect2, varscan2
- STARD3NL | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs749369688, COSV50517899; called by muse, mutect2, varscan2
- SYNE2 | c.10022C>G p.S3341* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as COSV59939320; called by muse, mutect2, varscan2
- SYNE2 | c.15025A>G p.I5009V | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1267693122, COSV59939325; called by muse, mutect2, varscan2
- SYNE2 | c.15871A>G p.M5291V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV59939332; called by muse, mutect2, varscan2
- SYT3 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58895413, COSV58895762; called by muse, mutect2, varscan2
- TBC1D15 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV59847336; called by mutect2, varscan2
- TMC7 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV58581448; called by muse, varscan2
- TMEM266 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs201833387, COSV66378494; called by muse, mutect2, varscan2
- TNFRSF21 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57279984; called by muse, mutect2, varscan2
- TRIM22 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66090141; called by muse, mutect2
- TRIM36 | c.1285G>T p.V429F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); catalogued as rs763661147, COSV56688056, COSV56692531; called by muse, mutect2, varscan2
- TRIM46 | c.2027G>T p.R676M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV58111350; called by muse, mutect2, varscan2
- TUBB2A | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV61318728; called by muse, mutect2, varscan2
- UNC5A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836784, COSV99458728; called by muse, mutect2, varscan2
- UNK | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53139266; called by muse, mutect2, varscan2
- UPK1B | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.994); catalogued as rs1315103376, COSV51766079; called by muse, mutect2, varscan2
- VPS50 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 57/193 reads (30%) | catalogued as COSV52492528, COSV52497528; called by muse, mutect2, varscan2
- ZNF496 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54173341, COSV99665210; called by muse, mutect2
- ZNF546 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs144973655; called by muse, mutect2, varscan2
- ZNF71 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100046029, COSV60146392; called by muse, mutect2, varscan2
- ARL5B | c.62dup p.V22Sfs*5 | Frame Shift Ins (INS) | VAF 50/201 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.71929del p.V23977Yfs*16 (on ENST00000591111; = p.V16553Yfs*16 on NM_003319.4) | Frame Shift Del (DEL) | VAF 113/490 reads (23%) | called by mutect2, pindel, varscan2
- ARHGEF6 | c.1920G>A p.S640= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs755538356, COSV51687414; called by muse, mutect2, varscan2
- BMT2 | c.372A>T p.V124= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV51774661; called by muse, mutect2, varscan2
- CEBPB | c.906G>A p.K302= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV57276740; called by muse, varscan2
- COL6A3 | c.3639G>C p.L1213= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV55079481; called by muse, mutect2, varscan2
- FYB2 | c.1071T>C p.Y357= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV58582826; called by muse, mutect2, varscan2
- GALNT17 | c.1644G>A p.L548= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1301940904, COSV100352845; called by muse, varscan2
- GPT2 | c.666C>T p.V222= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV60837431; called by muse, mutect2, varscan2
- HADHA | c.1539G>C p.T513= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV66106273; called by muse, mutect2, varscan2
- HMGB1 | c.312C>A p.L104= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV104396546, COSV58104113; called by muse, mutect2, varscan2
- IFI27L2 | c.108C>G p.S36= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV53127985, COSV53128255; called by muse, mutect2, varscan2
- JAG1 | c.2670C>T p.I890= | Silent (SNP) | VAF 37/261 reads (14%) | catalogued as rs776821383, COSV54753264; called by muse, mutect2, varscan2
- KLHL38 | c.252C>T p.T84= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV58085967; called by muse, mutect2, varscan2
- KRTAP13-1 | c.207C>T p.S69= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV62662788, COSV62663121; called by muse, mutect2, varscan2
- LONRF2 | c.522G>T p.P174= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV66539294; called by muse, mutect2, varscan2
- LRRIQ3 | c.321T>C p.N107= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV63040999; called by muse, mutect2, varscan2
- MAP3K4 | c.2883T>G p.A961= | Silent (SNP) | VAF 62/305 reads (20%) | catalogued as COSV62330081; called by muse, mutect2, varscan2
- MRGPRX4 | c.93G>A p.T31= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs777084382, COSV58589744; called by muse, mutect2, varscan2
- MUC17 | c.2868C>A p.T956= | Silent (SNP) | VAF 91/542 reads (17%) | catalogued as COSV100072733, COSV60279675; called by muse, mutect2, varscan2
- MYO3A | c.1500G>T p.A500= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV56319339; called by muse, mutect2, varscan2
- NDUFAF4 | c.492C>T p.F164= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV60213685; called by muse, mutect2, varscan2
- OR56A1 | c.795C>T p.N265= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as rs750242905, COSV57361753; called by muse, mutect2, varscan2
- OR5R1 | c.843G>A p.V281= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as rs752707132, COSV56571453, COSV56573568; called by muse, mutect2
- PLD5 | c.789A>G p.L263= (on ENST00000442594; = p.L201= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV59133053; called by muse, mutect2, varscan2
- PRKD1 | c.2238C>T p.T746= | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as COSV59559197; called by muse, mutect2, varscan2
- PRTN3 | c.759G>A p.K253= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52255047; called by muse, mutect2, varscan2
- RGL3 | c.192C>T p.S64= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV62697129; called by muse, mutect2, varscan2
- ROBO4 | c.2571G>A p.L857= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs371743207; called by muse, mutect2, varscan2
- SEPTIN9 | c.309G>T p.P103= (on ENST00000427177 / NM_001113491.2; = p.P85= on NM_006640.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61202163; called by muse, mutect2, varscan2
- SPANXN2 | c.231C>T p.S77= | Silent (SNP) | VAF 78/282 reads (28%) | catalogued as COSV65127663, COSV65128770; called by muse, varscan2
- SRGAP3 | c.2334G>A p.S778= | Silent (SNP) | VAF 65/272 reads (24%) | catalogued as rs770659662, COSV64530268; ClinVar: likely benign; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3378T>A p.V1126= | Silent (SNP) | VAF 39/309 reads (13%) | catalogued as COSV59125960; called by muse, mutect2, varscan2
- TTN | c.4566C>T p.P1522= (on ENST00000591111; = p.P1476= on NM_003319.4) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV59881213; called by muse, varscan2
- TTN | c.2751A>G p.E917= (on ENST00000591111; = p.E871= on NM_003319.4) | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as COSV59881250; called by muse, mutect2, varscan2
- ZAN | c.6480G>T p.T2160= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100769667, COSV61804806; called by muse, mutect2, varscan2
- ACMSD | c.*2T>G | 3'UTR (SNP) | VAF 24/160 reads (15%) | catalogued as COSV99298882; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1362G>C | Intron (SNP) | VAF 50/171 reads (29%) | catalogued as COSV99227811, COSV99229519; called by muse, mutect2, varscan2
